Gene-level copy-number profile of tumor specimen C3N-03849-01 (profiled together with C3N-03849-02) from CPTAC case C3N-03849, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 55.8 years (20,363 days).
Specimen C3N-03849-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a34dda68-b355-446f-a26a-14d5ffd9ce70.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03849-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/d3343b54-22cb-4595-88d7-917ed7c97c4c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 573; copy number 1: 2,443; copy number 2: 21,989; copy number 3: 28,100; copy number 4: 4,672; copy number 5: 649; copy number 6: 235; copy number 7: 73; copy number 8: 54; copy number 11: 12; copy number 12: 44; copy number 14: 65.

Homozygous deletions (total copy number 0; autosomes only): 54 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:80,746,339–80,746,819, 1 gene (within-gene range 0–2): AC022493.2.
- chr9:4,944,670–5,470,566, 25 genes: HNRNPA1P41, JAK2, CSNK1G2P1, PDSS1P1, MTND6P5, MTND1P11, MTCO1P11, MTCO2P11, MTATP6P11, MTCO3P11, MTND4P14, MTND5P14, TCF3P1, IGHEP2, INSL6, AL133547.1, INSL4, RLN2, HMGN2P31, RLN1, AL135786.2, AL135786.1, PLGRKT, RNF152P1, CD274.
- chr9:15,776,181–15,776,286, 1 gene (within-gene range 0–2): RNU6-14P.
- chr9:21,453,802–21,559,900, 1 gene (within-gene range 0–2): MIR31HG.
- chr9:21,480,839–22,455,740, 22 genes (within-gene range 0–2): IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr9:41,233,755–41,273,997, 3 genes: MIR4477A, RNA5SP530, AL845472.1.
- chr9:41,340,823–41,355,538, 1 gene: CDRT15P6.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 248 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:65,463,071–65,859,766, 14 genes, copy number 7: AC114501.3, AC114501.1, AC114501.2, AC104057.1, AC073107.1, INTS4P2, CCT6P1, SNORA22, SNORA15B-2, AC073107.2, GTF2IP5, RNU6-912P, AC093582.1, RNU6-973P.
- chr11:69,371,463–71,928,654, 77 genes, copy number 11–14 (broad region; genes not listed).
- chr11:72,836,745–73,142,318, 1 gene, copy number 7 (within-gene range 6–7): FCHSD2.
- chr11:73,157,946–74,738,796, 58 genes, copy number 7: AP002761.2, AP002761.1, P2RY2, AP002761.4, OR8R1P, P2RY6, AP002761.3, ARHGEF17, RELT, AP000763.4, FAM168A, AP000763.3, AP000763.1, AP000763.2, HMGN2P38, AP000860.1, PLEKHB1, RAB6A, AP002993.1, AP002770.1, MRPL48, RN7SKP243, CCDC58P5, COA4, PAAF1, ARPC3P4, DNAJB13, AP003717.1, UCP2, AP003717.2, AP003717.3, UCP3, C2CD3, AP002392.1, PPME1, RNA5SP343, AP000577.2, P4HA3, AP000577.1, P4HA3-AS1, PGM2L1, HNRNPA1P40, AP001372.1, AP001085.1, MIR548AL, KCNE3, AP001372.3, CYCSP27, AP001372.4, LIPT2, AP001372.2, POLD3, RANP3, RN7SKP297, CHRDL2, AP001324.3, MIR4696, AP001324.2.
- chr18:45,034–4,455,307, 98 genes, copy number 8–12 (within-gene range 6–12) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 197. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
